Somatic mutation profile of tumor specimen ALCH-ADUW-TTP1-A (aliquot ALCH-ADUW-TTP1-A-1-0-D-A549-36) from ALCHEMIST case ALCH-ADUW, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 52.6 years (19,216 days).
Specimen ALCH-ADUW-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3372adaa-4795-48b2-92df-164f6bb5d1a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADUW-NB1-A (Blood Derived Normal), aliquot ALCH-ADUW-NB1-A-1-0-D-A549-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d31fb3b0-fe35-428c-9a65-0aba319b8c83

The open-access MAF lists 46 somatic variants for this specimen: 30 protein-altering or splice-affecting, 12 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 12, Intron 2, 5'Flank 1, 5'UTR 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 204/606 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- CNGA2 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 27/166 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV61705390; called by muse, mutect2, varscan2
- CRB2 | c.2690C>T p.S897L | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as rs1279080183, COSV63505043; called by muse, mutect2, varscan2
- EPHB1 | c.1309G>A p.V437I | Missense Mutation (SNP) | VAF 45/202 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.235); catalogued as rs183234182; called by muse, mutect2, varscan2
- KRT75 | c.1498A>T p.S500C | Missense Mutation (SNP) | VAF 56/193 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.339); catalogued as COSV52872823; called by muse, mutect2, varscan2
- NLRP14 | c.2418G>T p.L806F | Missense Mutation (SNP) | VAF 147/673 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55067083; called by muse, mutect2, varscan2
- NUP93 | c.2014G>A p.E672K | Missense Mutation (SNP) | VAF 32/184 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.041); catalogued as rs764196494, COSV100360410; called by muse, mutect2, varscan2
- OR4S1 | c.589G>A p.V197M | Missense Mutation (SNP) | VAF 66/337 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.85); catalogued as rs777534434, COSV60679707; called by muse, mutect2, varscan2
- PPP1R3A | c.27G>T p.Q9H | Missense Mutation (SNP) | VAF 67/481 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.07); catalogued as COSV52890274; called by muse, mutect2, varscan2
- ROBO4 | c.803G>A p.W268* | Nonsense Mutation (SNP) | VAF 15/124 reads (12%) | catalogued as rs763674241; called by muse, mutect2, varscan2
- STAG2 | c.3452C>T p.T1151I | Missense Mutation (SNP) | VAF 99/243 reads (41%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.066); catalogued as COSV54374986; called by muse, mutect2, varscan2
- TRBV20OR9-2 | c.217C>T p.R73W | Missense Mutation (SNP) | VAF 13/301 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.274); catalogued as rs1392195755; called by muse, mutect2
- TTC9B | c.193G>T p.A65S | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs376663858; called by muse, mutect2, varscan2
- ABCA1 | c.3226C>G p.L1076V | Missense Mutation (SNP) | VAF 16/586 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); called by muse, mutect2
- AFF4 | c.3137T>G p.L1046W | Missense Mutation (SNP) | VAF 16/542 reads (3%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.877); called by muse, mutect2
- ASH1L | c.7526A>C p.E2509A (on ENST00000368346 / NM_001366177.2; = p.E2504A on NM_018489.3) | Missense Mutation (SNP) | VAF 32/446 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2
- CACNA1B | c.4874C>T p.A1625V | Missense Mutation (SNP) | VAF 54/292 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.898); called by muse, varscan2
- CFAP57 | c.353A>C p.D118A | Missense Mutation (SNP) | VAF 20/325 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- DNAH10 | c.9931G>T p.V3311F (on ENST00000409039; = p.V3250F on NM_207437.3) | Missense Mutation (SNP) | VAF 60/285 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ENTPD1 | c.1327A>G p.I443V | Missense Mutation (SNP) | VAF 101/565 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- GRIA3 | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 102/965 reads (11%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HLA-G | c.30C>A p.F10L | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITGA4 | c.784A>G p.S262G | Missense Mutation (SNP) | VAF 34/359 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2
- ITGA4 | c.785G>C p.S262T | Missense Mutation (SNP) | VAF 34/362 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.013); called by muse, mutect2
- NSG1 | c.502C>G p.L168V | Missense Mutation (SNP) | VAF 64/381 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- RAD51D | c.641del p.P214Hfs*13 | Frame Shift Del (DEL) | VAF 149/860 reads (17%) | called by mutect2, pindel, varscan2
- SLC8A2 | c.1285G>A p.V429M | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- STAT2 | c.1654C>G p.P552A | Missense Mutation (SNP) | VAF 40/243 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- TTN | c.11485C>A p.P3829T (on ENST00000591111; = p.P3783T on NM_003319.4) | Missense Mutation (SNP) | VAF 9/211 reads (4%) | called by muse, mutect2
- USP34 | c.9901T>C p.S3301P | Missense Mutation (SNP) | VAF 64/295 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- BCOR | c.960G>A p.A320= | Silent (SNP) | VAF 41/258 reads (16%) | catalogued as rs140219452; called by muse, mutect2, varscan2
- CCDC88C | c.1110G>T p.L370= | Silent (SNP) | VAF 41/295 reads (14%) | called by muse, mutect2, varscan2
- GRM3 | c.1260T>C p.D420= | Silent (SNP) | VAF 56/226 reads (25%) | called by muse, mutect2, varscan2
- HLA-G | c.31C>T p.L11= | Silent (SNP) | VAF 17/99 reads (17%) | called by muse, mutect2, varscan2
- HMCN2 | c.1830C>T p.S610= | Silent (SNP) | VAF 26/174 reads (15%) | catalogued as rs1320370152; called by muse, varscan2
- IDH3G | c.378G>A p.P126= | Silent (SNP) | VAF 34/296 reads (11%) | catalogued as rs782314768; called by muse, mutect2, varscan2
- ISLR | c.564C>T p.I188= | Silent (SNP) | VAF 29/112 reads (26%) | catalogued as rs138253214, COSV51433161, COSV51435233; called by muse, mutect2, varscan2
- MORC4 | c.1077A>G p.V359= | Silent (SNP) | VAF 96/406 reads (24%) | called by muse, mutect2, varscan2
- MUC16 | c.28596C>T p.L9532= | Silent (SNP) | VAF 28/118 reads (24%) | catalogued as rs773107651, COSV67463135; called by muse, mutect2, varscan2
- PLXNA4 | c.357C>A p.L119= | Silent (SNP) | VAF 31/250 reads (12%) | called by muse, mutect2, varscan2
- SPTBN4 | c.2247G>A p.A749= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as rs1368635926; called by muse, varscan2
- TRAJ20 | c.9C>T p.N3= | Silent (SNP) | VAF 26/214 reads (12%) | catalogued as rs754525320; called by muse, mutect2, varscan2
- CA2 | c.-2C>G | 5'UTR (SNP) | VAF 10/300 reads (3%) | called by muse, mutect2
- CCT5 | chr5:10250006 G>T | 5'Flank (SNP) | VAF 49/447 reads (11%) | called by muse, mutect2
- HELT | c.133-95T>C | Intron (SNP) | VAF 13/37 reads (35%) | called by muse, mutect2, varscan2
- TMEM175 | c.192+232C>T | Intron (SNP) | VAF 116/251 reads (46%) | catalogued as rs1427884911, COSV53279404; called by muse, mutect2, varscan2
